Somatic mutation profile of tumor specimen ALCH-B3EJ-TTP1-A (aliquot ALCH-B3EJ-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3EJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.8 years (25,868 days).
Specimen ALCH-B3EJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a1b97b1-4da1-4aad-815c-026d767e8005.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3EJ-NB1-A (Blood Derived Normal), aliquot ALCH-B3EJ-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ada6c6ec-ff4f-45f6-8e62-3d2be675f0cb

The open-access MAF lists 230 somatic variants for this specimen: 155 protein-altering or splice-affecting, 44 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 44, Intron 12, Nonsense Mutation 10, RNA 8, 3'UTR 5, 5'UTR 4, Splice Region 3, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.1351C>G p.L451V | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV101330161; called by muse, mutect2, varscan2
- AHNAK2 | c.8952G>C p.K2984N | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs762522122; called by muse, mutect2
- APOBEC1 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); catalogued as COSV57548732; called by muse, mutect2
- C2CD4A | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs764647346; called by muse, mutect2
- CACNA1S | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs377082783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMSAP1 | c.480C>G p.I160M | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1434574427; called by muse, mutect2
- CCDC154 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as rs1038519011; called by muse, mutect2
- CCNB3 | c.3718G>A p.E1240K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99329178; called by muse, mutect2
- CDT1 | c.1157C>G p.S386C | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs762360962, COSV56350397; called by muse, mutect2, varscan2
- CHD8 | c.6124G>T p.E2042* (on ENST00000646647 / NM_001170629.2; = p.E1763* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 22/135 reads (16%) | catalogued as rs1555313267; called by muse, mutect2, varscan2
- CHRNA2 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs866092045, CM1414139, COSV53560290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP3 | c.2289G>C p.Q763H | Missense Mutation (SNP) | VAF 32/385 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV52663568; called by muse, mutect2
- CTCF | c.1408C>G p.R470G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV50462363; called by muse, mutect2, varscan2
- DDI1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs199967405, COSV56375408; called by muse, mutect2, varscan2
- DMD | c.5288G>A p.R1763Q | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as COSV63757525; called by muse, mutect2, varscan2
- DNAI1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 28/529 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759540568; called by muse, mutect2
- DNAJC13 | c.4298C>T p.S1433L | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772470852; called by muse, mutect2
- DTX3L | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56145230; called by muse, mutect2
- EPO | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1327219318; called by muse, mutect2, varscan2
- ERBB3 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.344); catalogued as rs779069907, COSV57252537, COSV57264039; called by muse, mutect2
- FAT4 | c.6217C>G p.Q2073E | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs369260744; called by muse, mutect2, varscan2
- FBXO25 | c.547C>G p.L183V (on ENST00000382824 / NM_183421.2; = p.L116V on NM_012173.3) | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52336799; called by muse, mutect2, varscan2
- GAP43 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as rs773812326; called by muse, mutect2
- GDPD1 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV52380652, COSV52383956; called by muse, mutect2
- GK2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs149134428, COSV62626058, COSV62628077; called by muse, mutect2, varscan2
- GOLGA8M | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1014648703; called by muse, mutect2, varscan2
- H2BC4 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 21/372 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as COSV58417434; called by muse, mutect2
- H3C2 | c.18G>C p.Q6H | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1278314228, COSV52517760; called by muse, mutect2, varscan2
- HERC6 | c.2642G>C p.R881T | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs755006890; called by muse, mutect2, varscan2
- HTRA4 | c.1425C>G p.I475M | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs1207506201; called by muse, mutect2
- IL23R | c.1639G>A p.G547R | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs1353483558; called by muse, mutect2, varscan2
- ITPKB | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as rs1400865402, COSV55266478; called by muse, mutect2
- ITSN1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 104/520 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV66082918; called by muse, mutect2, varscan2
- KIAA0319 | c.2549C>G p.S850W | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs140038163; called by muse, varscan2
- L3MBTL1 | c.98C>G p.S33C (on ENST00000418998 / NM_001377303.1; = p.S11C on NM_032107.5) | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as rs199657419; called by muse, mutect2
- LAIR2 | c.7C>G p.P3A | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56620779; called by muse, mutect2, varscan2
- LOXHD1 | c.5512G>A p.E1838K (on ENST00000642948; = p.E1776K on NM_144612.7) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV56067842; called by muse, mutect2, varscan2
- LRRIQ3 | c.1493G>C p.R498T | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs779421222; called by muse, mutect2, varscan2
- MAGEB5 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV66868761; called by muse, mutect2, varscan2
- MAN2A2 | c.3140C>T p.S1047L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV64637082; called by muse, mutect2
- MFHAS1 | c.1443T>G p.D481E | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as COSV99360048; called by muse, mutect2
- MGA | c.8581C>T p.R2861W (on ENST00000219905 / NM_001164273.1; = p.R2652W on NM_001080541.2) | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs749267770, COSV54948011; called by muse, mutect2, varscan2
- MTMR2 | c.262+3C>T | Splice Region (SNP) | VAF 28/440 reads (6%) | catalogued as COSV100656804; called by muse, mutect2
- MUC16 | c.33686C>G p.S11229* | Nonsense Mutation (SNP) | VAF 20/142 reads (14%) | catalogued as COSV101200574; called by muse, mutect2, varscan2
- MYO6 | c.2788C>G p.Q930E | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV64120971; called by muse, mutect2
- NAP1L1 | c.438G>C p.L146F | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as COSV53874013; called by muse, mutect2
- NBPF15 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 19/554 reads (3%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.561); catalogued as rs1353894318; called by muse, mutect2
- NOBOX | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV99779506; called by muse, mutect2, varscan2
- NR2F6 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs758864042; called by muse, mutect2, varscan2
- NR4A3 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100432424; called by muse, mutect2, varscan2
- NXNL1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV57325167; called by muse, mutect2, varscan2
- OR4C11 | c.399C>G p.I133M | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56353536, COSV56353694; called by muse, mutect2, varscan2
- PARP14 | c.4392C>G p.I1464M | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV71735299; called by muse, mutect2, varscan2
- PHF11 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs987553181; called by muse, mutect2, varscan2
- PMFBP1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs370417430; called by muse, mutect2
- PPFIA3 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.235); catalogued as COSV100494703; called by muse, mutect2
- PRKD1 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 28/483 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV59566313; called by muse, mutect2
- PRX | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.287); catalogued as COSV52527962, COSV99397539; called by muse, mutect2, varscan2
- SEMA6C | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs761862225; called by muse, mutect2, varscan2
- SEPTIN5 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63531003; called by muse, mutect2
- SIRT7 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV100155803; called by muse, mutect2, varscan2
- SLA | c.650C>T p.P217L (on ENST00000338087 / NM_001045556.3; = p.P257L on NM_006748.4) | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs771316675, COSV55085463; called by muse, mutect2
- SLITRK1 | c.595G>C p.E199Q | Missense Mutation (SNP) | VAF 15/472 reads (3%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.54); catalogued as COSV100999873, COSV65675484; called by muse, mutect2
- SP100 | c.2332-1G>A p.X778_splice | Splice Site (SNP) | VAF 34/211 reads (16%) | catalogued as COSV60845890, COSV60850036; called by muse, mutect2, varscan2
- TCF7L2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs1243981730, COSV60504153, COSV60507235; called by muse, mutect2, varscan2
- TOGARAM1 | c.2462C>T p.S821L | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1460823253; called by muse, mutect2
- TTC5 | c.928C>G p.Q310E | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51870182; called by muse, mutect2
- WDFY3 | c.4000C>G p.L1334V | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs777174110; called by muse, mutect2, varscan2
- ZNF347 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100498231; called by muse, mutect2
- ALDH1A1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- ANKRD18B | c.2792T>A p.I931N | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- APOB | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 11/332 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATP1A2 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 32/442 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2
- ATP1A4 | c.2703G>C p.L901F | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BAZ2B | c.5933G>A p.C1978Y | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BRPF3 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 54/349 reads (15%) | called by muse, mutect2, varscan2
- CACTIN | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMTA2 | c.3122C>G p.S1041* | Nonsense Mutation (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- CCDC136 | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CRACR2A | c.1899C>G p.F633L | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2
- CRAMP1 | c.3188C>T p.S1063F | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CREM | c.415G>A p.E139K (on ENST00000429130; = p.E90K on NM_001881.3) | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); called by muse, mutect2
- DCHS2 | c.1312C>G p.R438G | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCUN1D2 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2
- DYNC1LI2 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.253); called by muse, mutect2
- EIF2B5 | c.1322C>T p.S441F (on ENST00000647909; = p.S433F on NM_003907.3) | Missense Mutation (SNP) | VAF 25/373 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2
- FER1L6 | c.1757C>G p.S586C | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- GLRA1 | c.380T>C p.F127S | Missense Mutation (SNP) | VAF 95/610 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GNMT | c.354G>C p.W118C | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HPS3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HSP90AB1 | c.61del p.I21Lfs*23 | Frame Shift Del (DEL) | VAF 21/198 reads (11%) | called by mutect2, pindel, varscan2
- ITIH2 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 24/160 reads (15%) | called by muse, varscan2
- KCNH1 | c.1701C>G p.I567M (on ENST00000271751 / NM_172362.3; = p.I540M on NM_002238.4) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- KRT10 | c.112A>T p.S38C | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT3 | c.985_989dup p.D330Efs*2 | Nonsense Mutation (INS) | VAF 16/182 reads (9%) | called by mutect2, pindel
- MFHAS1 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2
- MFHAS1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.06); called by muse, mutect2
- MINDY2 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); called by muse, mutect2
- MINDY4B | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MROH2B | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYCL | c.77G>A p.S26N (on ENST00000372816 / NM_001033081.3; = p.S56N on NM_005376.5) | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NANS | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); called by muse, mutect2
- NPC1L1 | c.2957C>T p.S986F | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- NPIPB6 | c.1068A>T p.K356N | Missense Mutation (SNP) | VAF 44/696 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- NSD3 | c.2525C>G p.S842C | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2
- NUP210 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OPRPN | c.149del p.P50Hfs*60 | Frame Shift Del (DEL) | VAF 45/280 reads (16%) | called by mutect2, pindel, varscan2
- OR51A4 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.034); called by muse, mutect2
- OTOL1 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2
- OTUD1 | c.1176C>G p.I392M | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PAN3 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PCDH15 | c.5194G>T p.E1732* | Nonsense Mutation (SNP) | VAF 40/224 reads (18%) | called by muse, mutect2, varscan2
- PER2 | c.3444G>A p.M1148I | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- PIANP | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- PKP3 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); called by muse, mutect2
- PRIMPOL | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PRX | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PYCR1 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- RALGAPA2 | c.1886C>G p.S629C | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RBP3 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- RIN1 | c.383-7C>G | Splice Region (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2, varscan2
- ROBO1 | c.2164G>C p.D722H | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- SAFB2 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEMA6C | c.2614C>G p.P872A | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- SEMA6C | c.1799C>G p.S600C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SEPTIN12 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SETD2 | c.2749dup p.S917Kfs*18 | Frame Shift Ins (INS) | VAF 19/100 reads (19%) | called by mutect2, varscan2
- SHROOM4 | c.3928C>G p.L1310V | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2
- SIRT7 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC5A6 | c.1648G>A p.G550R | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SNRPA | c.827_829del p.K276del | In Frame Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- SPAG9 | c.2329C>A p.Q777K (on ENST00000262013 / NM_001130528.3; = p.Q763K on NM_003971.6) | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2
- SPATA31A6 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 30/696 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2
- SSH2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SYAP1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.141); called by muse, mutect2
- TAF7 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- TBC1D14 | c.763C>G p.H255D | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2
- TCIRG1 | c.1031G>C p.G344A | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TDP2 | c.1060C>G p.L354V | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.264); called by muse, mutect2
- TEDC2 | c.1095G>C p.Q365H | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TIGD5 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TMEM244 | c.185A>C p.N62T | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- TMPRSS11F | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, varscan2
- TNFRSF10B | c.1008G>A p.E336= | Splice Region (SNP) | VAF 22/438 reads (5%) | called by muse, mutect2
- TP63 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 55/348 reads (16%) | called by muse, mutect2, varscan2
- TRAV23DV6 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2
- TTC28 | c.7336C>A p.L2446M | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TYW1B | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 48/325 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- UBR3 | c.2712G>C p.K904N | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- UNC93A | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZAN | c.2671G>T p.E891* | Nonsense Mutation (SNP) | VAF 32/226 reads (14%) | called by muse, varscan2
- ZFC3H1 | c.3952C>T p.Q1318* | Nonsense Mutation (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- ZHX3 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2
- ZMYM3 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ZNF677 | c.1264C>G p.Q422E | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); called by muse, mutect2
- ABHD1 | c.81C>G p.L27= | Silent (SNP) | VAF 34/235 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.1419C>T p.H473= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs758260638, COSV51088534; called by muse, mutect2, varscan2
- ALKBH3 | c.297G>A p.V99= | Silent (SNP) | VAF 22/271 reads (8%) | called by muse, mutect2
- CCDC127 | c.627C>T p.L209= | Silent (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2, varscan2
- CCDC184 | c.450C>T p.P150= | Silent (SNP) | VAF 4/82 reads (5%) | catalogued as rs1182170576; called by muse, mutect2
- CCR2 | c.219G>A p.L73= | Silent (SNP) | VAF 24/287 reads (8%) | catalogued as COSV99432779; called by muse, mutect2
- CHD3 | c.5556G>T p.A1852= (on ENST00000330494 / NM_001005273.3; = p.A1818= on NM_005852.4) | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as rs772056098, COSV57875592; called by muse, mutect2, varscan2
- CNN2 | c.18C>T p.F6= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as rs766525216; called by muse, mutect2
- DNPEP | c.159C>G p.L53= | Silent (SNP) | VAF 18/219 reads (8%) | called by muse, mutect2
- EPM2A | c.870G>A p.R290= | Silent (SNP) | VAF 23/418 reads (6%) | catalogued as rs770041557; ClinVar: likely benign; called by muse, mutect2
- FARP2 | c.2634C>T p.N878= | Silent (SNP) | VAF 22/179 reads (12%) | catalogued as rs754794761, COSV50885880; called by muse, mutect2, varscan2
- FBXO10 | c.2550C>T p.Y850= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs376228541, COSV52833583; called by muse, mutect2
- FLOT1 | c.684C>T p.N228= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as rs1480777962; called by muse, mutect2
- GLG1 | c.69C>T p.F23= | Silent (SNP) | VAF 19/125 reads (15%) | catalogued as rs1379166917, COSV99215332; called by muse, mutect2, varscan2
- HEATR5A | c.5316G>A p.G1772= | Silent (SNP) | VAF 24/522 reads (5%) | catalogued as COSV101119930; called by muse, mutect2
- IPPK | c.810G>C p.L270= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as COSV99845323; called by muse, mutect2
- ITIH2 | c.2337C>T p.T779= | Silent (SNP) | VAF 50/262 reads (19%) | called by muse, varscan2
- KLHL4 | c.1353C>T p.L451= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- MAGEB1 | c.354C>T p.F118= | Silent (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- MAML3 | c.78C>T p.L26= | Silent (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- MYO9A | c.6726G>A p.L2242= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV100613462; called by muse, mutect2, varscan2
- NPR1 | c.1824C>T p.I608= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as rs951530411; called by muse, mutect2
- NR4A3 | c.39A>G p.P13= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as rs1337239151; called by muse, mutect2
- OR10Z1 | c.183C>T p.L61= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- OR13C3 | c.621C>T p.F207= | Silent (SNP) | VAF 57/308 reads (19%) | catalogued as rs779347800, COSV66165647; called by muse, mutect2, varscan2
- OR5AU1 | c.828C>T p.V276= | Silent (SNP) | VAF 16/259 reads (6%) | called by muse, mutect2
- OR6Q1 | c.816C>T p.I272= | Silent (SNP) | VAF 14/359 reads (4%) | called by muse, mutect2
- PAFAH1B2 | c.126A>G p.V42= | Silent (SNP) | VAF 29/289 reads (10%) | catalogued as rs767950244; called by muse, mutect2
- PDK2 | c.24G>A p.L8= | Silent (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- PHAX | c.255G>A p.Q85= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as COSV52551328; called by muse, mutect2
- RTN4 | c.69C>T p.F23= | Silent (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- SLC1A5 | c.573C>T p.I191= | Silent (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
- SLC6A9 | c.765C>G p.L255= (on ENST00000360584 / NM_201649.4; = p.L201= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- SOS1 | c.2022G>A p.L674= | Silent (SNP) | VAF 36/325 reads (11%) | called by muse, mutect2, varscan2
- ST6GALNAC1 | c.888C>G p.L296= | Silent (SNP) | VAF 24/199 reads (12%) | catalogued as COSV50074131; called by muse, mutect2, varscan2
- TCP11 | c.492C>G p.L164= (on ENST00000512012; = p.L102= on NM_018679.5) | Silent (SNP) | VAF 51/315 reads (16%) | called by muse, mutect2, varscan2
- THSD4 | c.2400C>T p.T800= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs539524982, COSV55975729; called by muse, mutect2, varscan2
- TOX2 | c.1090C>T p.L364= (on ENST00000358131 / NM_001098798.2; = p.L340= on NM_032883.3) | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- TTC27 | c.2103G>A p.V701= | Silent (SNP) | VAF 36/517 reads (7%) | called by muse, mutect2
- TTLL6 | c.249G>C p.V83= | Silent (SNP) | VAF 58/462 reads (13%) | called by muse, mutect2, varscan2
- WHRN | c.318C>T p.F106= | Silent (SNP) | VAF 20/292 reads (7%) | called by muse, mutect2
- WNT16 | c.306G>T p.P102= (on ENST00000222462 / NM_057168.2; = p.P92= on NM_016087.2) | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV55975214; called by muse, mutect2, varscan2
- ZER1 | c.2188C>T p.L730= | Silent (SNP) | VAF 14/203 reads (7%) | called by muse, mutect2
- ZFC3H1 | c.3951C>T p.F1317= | Silent (SNP) | VAF 22/371 reads (6%) | called by muse, mutect2
- ACBD6 | c.*50G>A | 3'UTR (SNP) | VAF 17/239 reads (7%) | called by muse, mutect2
- ALDH6A1 | c.348+10C>G | Intron (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- ANKRD11 | c.-429G>A | 5'UTR (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- ASB9P1 | n.168C>T | RNA (SNP) | VAF 19/337 reads (6%) | called by muse, mutect2
- COG6 | c.153+284G>A | Intron (SNP) | VAF 35/252 reads (14%) | called by muse, mutect2, varscan2
- DNAI2 | c.1347+119C>T | Intron (SNP) | VAF 27/247 reads (11%) | catalogued as rs1338455289; called by muse, mutect2, varscan2
- ETFA | c.-24G>A | 5'UTR (SNP) | VAF 47/231 reads (20%) | called by muse, mutect2, varscan2
- FCGBP | c.*2C>T | 3'UTR (SNP) | VAF 30/248 reads (12%) | called by muse, mutect2, varscan2
- GOSR2 | c.-33G>A | 5'UTR (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2
- GRIK2 | c.2563-2517T>C | Intron (SNP) | VAF 12/91 reads (13%) | catalogued as COSV59749293; called by muse, mutect2, varscan2
- HLA-F | chr6:29726907 T>G | 3'Flank (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.31G>C | RNA (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- IDO2 | c.435-13G>A | Intron (SNP) | VAF 32/228 reads (14%) | catalogued as rs1249063454; called by muse, mutect2, varscan2
- LINC00452 | n.702C>T | RNA (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- MACF1 | c.543+11426G>A | Intron (SNP) | VAF 22/298 reads (7%) | called by muse, mutect2
- MAZ | c.*822_*824del | 3'UTR (DEL) | VAF 12/86 reads (14%) | catalogued as rs1384204551; called by pindel, varscan2
- MIRLET7BHG | n.189G>C | RNA (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
- MSC-AS1 | n.311C>T | RNA (SNP) | VAF 12/187 reads (6%) | called by muse, mutect2
- PALLD | c.1965-12585C>T | Intron (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- PARGP1 | n.249A>G | RNA (SNP) | VAF 30/193 reads (16%) | called by muse, mutect2, varscan2
- PTPRVP | n.4144-30_4144-29insCCTCGCTCCTTGCTCCTCGCTCCTCGCT | Intron (INS) | VAF 11/146 reads (8%) | called by muse*, mutect2
- RAB37 | chr17:74736695 G>A | 5'Flank (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- ROGDI | c.117+387C>A | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- SCN3B | c.584+10G>C | Intron (SNP) | VAF 73/524 reads (14%) | called by muse, mutect2, varscan2
- SCN4B | c.*292G>C | 3'UTR (SNP) | VAF 41/318 reads (13%) | called by muse, mutect2, varscan2
- SLC25A29 | c.*82C>A | 3'UTR (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- SNORD116-22 | n.86G>A | RNA (SNP) | VAF 53/291 reads (18%) | called by muse, mutect2, varscan2
- SYT17 | c.1229-16886A>T | Intron (SNP) | VAF 32/294 reads (11%) | called by muse, mutect2
- TLDC2 | c.-4G>C | 5'UTR (SNP) | VAF 30/167 reads (18%) | catalogued as COSV99455703; called by muse, mutect2, varscan2
- TP73-AS1 | n.1216C>T | RNA (SNP) | VAF 22/246 reads (9%) | catalogued as rs775672033; called by muse, mutect2
- YBX1 | c.166+322C>T | Intron (SNP) | VAF 7/109 reads (6%) | catalogued as rs1279406241; called by muse, mutect2
